Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5107, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5107-01A (Primary Tumor).

FINAL DIAGNOSIS:

KIDNEY, RIGHT, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, UNCLASSIFIED TYPE WITH A HYBRID PATTERN OF HISTOLOGICAL TYPES INCLUDING CLEAR CELL, PAPILLARY AND EOSINOPHILIC COMPONENTS (SEE DIAGNOSIS COMMENT).
- B. FUHRMAN NUCLEAR GRADE IS III-IV OF IV.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 8 cm.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED. NO INVASION OF RENAL ARTERY OR URETER IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. NO INVASION OF RENAL PELVIS IS IDENTIFIED.
- I. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- J. TNM STAGE: pT2 NX MX.

Source: NCI Genomic Data Commons file c56f6cf4-17da-48a7-b236-748acb51a48e (TCGA-B0-5107.241AA004-447A-4DAF-97EB-0EF5C4FCB4DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).